Surgical pathology report (de-identified scan), TCGA case TCGA-WC-A880, project TCGA-UVM (Uveal Melanoma), tissue source site MD Anderson, specimen TCGA-WC-A880-01A (Primary Tumor).

Accession:
Specimen Date/Time:

C66F

ICD-O-3

Melanoma, epithelioid & spindle cell

metastasis 8770/3

Melanoma, epithelioid cell 8771/3

Site: Choroid, C69.3

9/11/16/14

DIAGNOSIS

(A) RIGHT GLOBE, ENUCLEATION:

CHOROIDAL MELANOMA, PREDOMINATELY EPITHELIOID TYPE, 20 MM BASE.
FOCAL CHOROIDAL INVASION PRESENT
TUMOR SURROUNDS OPTIC NERVE
Extraocular extension is not identified.
Vortex veins negative for tumor.

COMMENT

The tumor erodes Bruch's membrane. Mitoses are 2 per 10 high power fields. PAS highlights internal structures and vasculature.

GROSS DESCRIPTION

(A) RIGHT GLOBE - An intact right globe (23 x 22 x 22 mm), has an attached optic nerve (9 mm in length). The anterior chamber is clear formed by a 12 x 11 gray iris with round 8 mm pupil. A shadow is present in the posterior aspect in a curvilinear fashion beginning 6.0 mm from the limbus. The shadow corresponds to a brown tumor, with a base of 20 mm by a 9 mm height that surrounds the optic disc which is not visualized. The sclera beneath the tumor is grossly intact. The vitreous is clear and a lens is in place. Tumor harvest is performed.

SECTION CODE: A1-A4, vortex veins (superior temporal, superior nasal, inferior nasal, inferior temporal); A5, pupillary nerve section; A6-A7 calottes also with tumor; A8 optic nerve including margin en face.

CLINICAL HISTORY

Uveal melanoma.

SNOMED CODES

T-AA000, M-87203

"Some tests reported here may have been developed and performance characteristics determined by
specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

These tests have not

-----END OF REPORT-----

Path	10/31/13	Yes	No
Pathologic			
Immunohistochemistry			
Molecular			
Flow Cytometry			
Microarray			
Next-Generation Sequencing			
Other			
Pathologist	10/7/13		

Source: NCI Genomic Data Commons file 01b95ea5-39a1-4f93-82b7-7bf530f85d87 (TCGA-WC-A880.A0BBA530-98EA-4989-9ABC-26A92615EF27.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).